Somatic mutation profile of tumor specimen TCGA-HU-A4GF-01A (aliquot TCGA-HU-A4GF-01A-11D-A24D-08) from TCGA case TCGA-HU-A4GF, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tubular adenocarcinoma; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 69.1 years (25,223 days).
Specimen TCGA-HU-A4GF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff524fc6-6c4e-4646-a27e-7d6067df8005.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4GF-10A (Blood Derived Normal), aliquot TCGA-HU-A4GF-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b764c95-8f03-4d2c-b412-8bb5177a48cf

The open-access MAF lists 149 somatic variants for this specimen: 117 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 94, Silent 30, Frame Shift Del 8, Nonsense Mutation 4, Splice Site 4, Frame Shift Ins 3, In Frame Del 2, Nonstop Mutation 1, RNA 1, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP2R1A | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 16/64 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786205227, CM153572, COSV59042121; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.388C>G p.L130V | Missense Mutation (SNP) | VAF 22/34 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs863224683, CM016206, COSV52686543, COSV52692226, COSV99368721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC093246.1 | c.265C>G p.R89G | Missense Mutation (SNP) | VAF 6/31 reads (19%) | catalogued as COSV51130108; called by muse, mutect2, varscan2
- ADAM22 | c.2339A>T p.D780V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.844); catalogued as COSV55992272; called by muse, mutect2, varscan2
- AK7 | c.517T>C p.F173L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.217); catalogued as rs1329454553, COSV50884454; called by muse, mutect2, varscan2
- AKAP11 | c.3122A>T p.K1041M | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.891); catalogued as COSV50304261; called by muse, mutect2, varscan2
- ALG14 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.272); catalogued as COSV64636250; called by muse, mutect2, varscan2
- ANK1 | c.3034G>A p.E1012K | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as rs907775044, COSV55877464; called by muse, mutect2, varscan2
- ANO2 | c.2226C>A p.Y742* (on ENST00000356134 / NM_001278597.3; = p.Y746* on NM_001278596.3) | Nonsense Mutation (SNP) | VAF 89/232 reads (38%) | catalogued as COSV59039109, COSV59046308; called by muse, mutect2, varscan2
- ANP32A | c.76A>C p.N26H | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51190022; called by muse, mutect2, varscan2
- AP5Z1 | c.2296T>C p.F766L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.284); catalogued as COSV62244134; called by muse, mutect2, varscan2
- ARFGEF1 | c.3454A>G p.M1152V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs781692371, COSV51618526; called by muse, mutect2, varscan2
- ARFGEF1 | c.218A>G p.N73S | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV51618535; called by muse, mutect2, varscan2
- ARHGEF26 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.255); catalogued as rs778948077, COSV100726665, COSV62852700; called by muse, mutect2, varscan2
- BSN | c.6672G>A p.M2224I | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs1309495389; called by muse, mutect2
- C12orf50 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs189840625, COSV53893594; called by muse, mutect2, varscan2
- CACNA1B | c.1036T>G p.F346V | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53152106; called by muse, mutect2, varscan2
- CALCRL | c.48del p.F16Lfs*2 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs1486659949; called by mutect2, pindel, varscan2
- CAMTA1 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 6/152 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs1057524631, COSV57882651; ClinVar: uncertain significance; called by muse, mutect2
- CCDC180 | c.3911C>T p.P1304L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs202030409; called by muse, mutect2, varscan2
- CDH23 | c.5485C>T p.P1829S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99818911, COSV99819948; called by muse, mutect2
- CELSR3 | c.2810G>A p.G937D | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51170984; called by muse, mutect2, varscan2
- CEP192 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1441425048, COSV58071538; called by muse, mutect2, varscan2
- CLEC11A | c.334C>T p.L112= | Splice Region (SNP) | VAF 14/38 reads (37%) | catalogued as COSV51575260, COSV99141609; called by muse, mutect2, varscan2
- CLIP1 | c.3368T>G p.L1123W (on ENST00000620786 / NM_001247997.1; = p.L1112W on NM_002956.2) | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56809582; called by muse, mutect2
- CNTN4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs576375620, COSV68562864; called by muse, mutect2, varscan2
- COX19 | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 27/636 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769215552, COSV100700412; called by muse, mutect2
- CSMD1 | c.8760C>A p.F2920L (on ENST00000520002; = p.F2919L on NM_033225.6) | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.046); catalogued as COSV59394247; called by muse, mutect2, varscan2
- CTNND2 | c.323-1G>A p.X108_splice | Splice Site (SNP) | VAF 13/107 reads (12%) | catalogued as COSV58933932; called by muse, mutect2, varscan2
- DCC | c.4241A>T p.E1414V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV71442019; called by muse, mutect2, varscan2
- DNAH7 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1356980468, COSV56777864, COSV56790094; called by muse, mutect2
- DNAH9 | c.8654C>A p.A2885D | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52380523; called by muse, mutect2, varscan2
- DNAJC14 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs1460496930, COSV57914600; called by muse, mutect2, varscan2
- FAM83B | c.2107T>A p.L703M | Missense Mutation (SNP) | VAF 65/143 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as COSV60927681; called by muse, mutect2, varscan2
- FAT4 | c.14355_14357del p.P4786del | In Frame Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs763946287; called by pindel, varscan2
- FLG | c.1321G>A p.G441R | Missense Mutation (SNP) | VAF 198/287 reads (69%) | SIFT tolerated (0.26); PolyPhen benign (0.334); catalogued as rs779690124, COSV64239340; called by muse, mutect2, varscan2
- FLI1 | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.049); catalogued as rs776142665, COSV55648346; called by muse, mutect2, varscan2
- FMN2 | c.2443T>C p.S815P | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.007); catalogued as COSV60457879; called by muse, mutect2, varscan2
- FMN2 | c.3347C>T p.A1116V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201396397, COSV60419928; called by muse, varscan2
- FRMD4B | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as rs750455183, COSV68334065; called by muse, mutect2, varscan2
- GCNA | c.624C>G p.N208K | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1463156881, COSV65465993, COSV65466214; called by muse, varscan2
- H2AW | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs762265732, COSV64210266; called by muse, mutect2, varscan2
- HMCN1 | c.1205T>A p.F402Y | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.85); catalogued as COSV54947016; called by muse, mutect2, varscan2
- HMGCS1 | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 38/184 reads (21%) | catalogued as COSV57291025, COSV57291912; called by muse, mutect2, varscan2
- ICAM4 | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV53427642; called by muse, mutect2, varscan2
- IGSF9B | c.1073A>T p.K358M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV58073799; called by muse, mutect2, varscan2
- IRX4 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.054); catalogued as rs760005454, COSV51471252; called by muse, mutect2, varscan2
- ITGAV | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV53719989; called by muse, mutect2, varscan2
- JCAD | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as rs563388639, COSV64758456; called by muse, mutect2, varscan2
- KANK1 | c.3897+1G>A p.X1299_splice | Splice Site (SNP) | VAF 12/29 reads (41%) | catalogued as rs758108591, COSV66527195; called by muse, mutect2
- KCNV1 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52089543; called by muse, mutect2, varscan2
- KMT5B | c.919T>G p.Y307D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58570166; called by muse, mutect2, varscan2
- KRT19 | c.180del p.Y61Tfs*9 | Frame Shift Del (DEL) | VAF 61/260 reads (23%) | catalogued as rs1342518531; called by mutect2, pindel, varscan2
- LRIT1 | c.1631C>T p.T544M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs375680820; called by muse, mutect2, varscan2
- LRRK2 | c.2126A>C p.K709T | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.786); catalogued as COSV54173849; called by muse, mutect2, varscan2
- LTBR | c.1037A>G p.N346S | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as rs1320483600, COSV57440035; called by muse, mutect2, varscan2
- LUC7L3 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0.085); catalogued as COSV53589912; called by muse, mutect2
- LYST | c.7060C>G p.L2354V | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.387); catalogued as COSV67715274; called by muse, mutect2
- MAGEB10 | c.696A>C p.L232F | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV63311066; called by muse, mutect2, varscan2
- MEX3D | c.970C>T p.P324S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV66312584; called by muse, mutect2
- MS4A14 | c.738A>C p.E246D | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV55738821; called by muse, mutect2, varscan2
- MSR1 | c.818-1G>T p.X273_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as rs772978107, CS061306, COSV50541813; called by muse, mutect2, varscan2
- MST1R | c.1540G>C p.G514R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56574912; called by muse, mutect2
- MXRA5 | c.4543A>T p.S1515C | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV54253297; called by muse, mutect2, varscan2
- NEUROD4 | c.890C>A p.P297H | Missense Mutation (SNP) | VAF 167/568 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV54471307, COSV54474545; called by muse, mutect2, varscan2
- NIPBL | c.7840A>G p.I2614V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.228); catalogued as rs1352584267, COSV56968368; called by muse, mutect2, varscan2
- NRXN1 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.169); catalogued as rs756844822, COSV60486238; called by muse, mutect2, varscan2
- NTRK2 | c.2239T>G p.F747V (on ENST00000323115 / NM_001369534.1; = p.F763V on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52885779; called by muse, mutect2, varscan2
- NUDT3 | c.381A>T p.K127N | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV70444551; called by muse, mutect2, varscan2
- OBSCN | c.5461G>A p.E1821K | Missense Mutation (SNP) | VAF 60/74 reads (81%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.734); catalogued as rs371895674; called by muse, mutect2, varscan2
- PCDHA9 | c.1061C>T p.T354M | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.336); catalogued as COSV65333855; called by muse, mutect2, varscan2
- PCDHB6 | c.2314T>G p.F772V | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.23); catalogued as COSV50692394, COSV50740114; called by muse, mutect2, varscan2
- PCYT1B | c.225G>T p.R75S | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV63266808; called by muse, mutect2
- PGLYRP4 | c.1121G>T p.*374Lext*194 | Nonstop Mutation (SNP) | VAF 18/103 reads (17%) | catalogued as COSV62836565; called by muse, mutect2, varscan2
- PHGDH | c.1111A>C p.S371R | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV65572822; called by muse, mutect2, varscan2
- PLA2G4A | c.2060A>G p.N687S | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.416); catalogued as COSV66557552; called by muse, mutect2, varscan2
- POLB | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs201913498, COSV55346962; called by muse, mutect2, varscan2
- PPP2CB | c.746A>G p.N249S | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1296593420, COSV55329798; called by muse, mutect2, varscan2
- REG1B | c.494A>C p.K165T | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV59308264; called by muse, mutect2, varscan2
- RND3 | c.251A>G p.Y84C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55726239; called by muse, mutect2, varscan2
- SCN5A | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0.058); catalogued as rs368552426, CM094264; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.2345C>T p.T782M | Missense Mutation (SNP) | VAF 58/85 reads (68%) | SIFT tolerated (0.11); PolyPhen benign (0.066); catalogued as rs763496362, COSV66789203; called by muse, mutect2, varscan2
- SETD4 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV59774469; called by muse, mutect2, varscan2
- SGK2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751865521, COSV58312277; called by muse, mutect2, varscan2
- SKOR1 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV58245558; called by muse, mutect2, varscan2
- SLC30A3 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752716923, COSV51985154; called by muse, mutect2, varscan2
- SLC7A7 | c.1366T>C p.F456L | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV53537022, COSV53538722; called by mutect2, varscan2
- SMAD1 | c.437A>G p.Y146C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1364163583, COSV57473709; called by muse, mutect2, varscan2
- SMARCA1 | c.2743A>C p.I915L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV64414111; called by muse, mutect2, varscan2
- SMC3 | c.1825A>G p.M609V | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV62422785; called by muse, mutect2, varscan2
- SPAG1 | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs144608097, COSV52561561; called by muse, mutect2
- SPEG | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs765114391, COSV56681138; called by muse, mutect2, varscan2
- SPHKAP | c.8G>A p.G3D | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as COSV60896851; called by muse, mutect2, varscan2
- SPTA1 | c.6680T>C p.L2227P | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1192314908, COSV63760873; called by muse, mutect2, varscan2
- SPTA1 | c.3416A>G p.K1139R | Missense Mutation (SNP) | VAF 56/248 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV63760877; called by muse, mutect2, varscan2
- TAX1BP1 | c.1760A>G p.Y587C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV55290505, COSV55297544; called by muse, mutect2
- TEX29 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs781602465, COSV52094785; called by muse, mutect2, varscan2
- TMEM168 | c.1547G>C p.G516A | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100454576; called by muse, mutect2
- TOX2 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.369); catalogued as rs765817011, COSV57897118; called by muse, mutect2
- TRGV3 | c.348G>T p.W116C | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1012049313; called by muse, mutect2, varscan2
- UNC79 | c.1627G>A p.D543N (on ENST00000393151 / NM_001346218.2; = p.D366N on NM_020818.5) | Missense Mutation (SNP) | VAF 64/95 reads (67%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV56415519; called by muse, mutect2, varscan2
- USP29 | c.1440A>C p.E480D | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54147292; called by muse, mutect2, varscan2
- VPS54 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 13/254 reads (5%) | catalogued as COSV55446099; called by muse, mutect2
- ZAN | c.1796C>A p.T599N | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV61817938; called by muse, mutect2, varscan2
- ZNF2 | c.874C>T p.H292Y (on ENST00000611147 / NM_001291605.2; = p.H279Y on NM_021088.4) | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54638561; called by muse, mutect2, varscan2
- ZNF41 | c.2321G>A p.R774H | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV57444275; called by muse, mutect2, varscan2
- ZNF609 | c.2201dup p.K735Efs*8 | Frame Shift Ins (INS) | VAF 60/208 reads (29%) | catalogued as rs760768847; called by mutect2, varscan2
- CKAP5 | c.5510_5526del p.F1837* (on ENST00000529230 / NM_001008938.4; = p.F1777* on NM_014756.3) | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel
- ERGIC3 | c.982_983del p.S328Afs*50 | Frame Shift Del (DEL) | VAF 14/120 reads (12%) | called by pindel, varscan2
- HIP1R | c.2986dup p.A996Gfs*2 | Frame Shift Ins (INS) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- IAH1 | c.546_550dup p.M184Tfs*2 | Frame Shift Ins (INS) | VAF 8/63 reads (13%) | called by mutect2, pindel
- NRG3 | c.1227_1266del p.S410Mfs*15 | Frame Shift Del (DEL) | VAF 20/42 reads (48%) | called by mutect2, pindel
- PLEKHA4 | c.1435_1485del p.S479_G495del | In Frame Del (DEL) | VAF 6/29 reads (21%) | called by mutect2, pindel
- PREPL | c.2034del p.N679Ifs*4 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- SBK2 | c.978del p.R327Afs*? (on ENST00000344158; = p.R327Afs*78 on NM_001370096.2) | Frame Shift Del (DEL) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- TFB1M | c.234_237del p.A79Nfs*26 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- UBA7 | c.218_225+38del p.X73_splice | Splice Site (DEL) | VAF 24/110 reads (22%) | called by mutect2, pindel
- ABHD12B | c.372G>A p.K124= (on ENST00000337334 / NM_001206673.2; = p.K47= on NM_181533.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV61571132; called by muse, mutect2
- ACE | c.714C>T p.D238= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as rs556856171, COSV52005172; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.2832T>C p.V944= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV67140901; called by muse, mutect2, varscan2
- ARL4D | c.210C>T p.I70= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs1187910093, COSV60721980; called by muse, mutect2, varscan2
- BAIAP2L2 | c.390G>T p.A130= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100207292, COSV60202966; called by muse, mutect2, varscan2
- BCL2L15 | c.202T>C p.L68= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV63643438; called by muse, mutect2, varscan2
- CACNA1I | c.4800G>A p.K1600= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1348384138, COSV100359756; called by muse, mutect2
- CAPN12 | c.411C>T p.G137= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs750875697, COSV61018983; called by muse, mutect2, varscan2
- CCDC116 | c.1509G>A p.E503= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV53042902; called by muse, mutect2
- CDH7 | c.1065G>A p.L355= | Silent (SNP) | VAF 40/90 reads (44%) | catalogued as COSV59886136, COSV59898200; called by muse, mutect2, varscan2
- CYP3A4 | c.1155G>A p.G385= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV60504571; called by muse, mutect2, varscan2
- DMKN | c.900C>T p.S300= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs781719489, COSV60087795; called by muse, mutect2
- F13A1 | c.489T>C p.A163= | Silent (SNP) | VAF 36/148 reads (24%) | catalogued as rs1370603880, COSV53569089; called by muse, mutect2, varscan2
- FAT3 | c.2154T>C p.I718= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as rs982502822, COSV53183148; called by muse, mutect2, varscan2
- GCK | c.58C>T p.L20= | Silent (SNP) | VAF 16/260 reads (6%) | catalogued as COSV61755769; called by muse, mutect2
- GRM3 | c.810C>T p.R270= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as COSV64480463, COSV64480794; called by muse, mutect2, varscan2
- KCNB1 | c.840C>T p.T280= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs748523037, COSV65570796; called by muse, mutect2, varscan2
- KHDC3L | c.246C>T p.N82= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as rs760211661, COSV64869858; called by muse, mutect2, varscan2
- LDHAL6B | c.582T>C p.Y194= | Silent (SNP) | VAF 141/207 reads (68%) | catalogued as rs762913697, COSV55696936; called by muse, mutect2, varscan2
- MED15 | c.1884C>T p.N628= (on ENST00000263205 / NM_001003891.3; = p.N588= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as rs1157202779, COSV53034206; called by muse, mutect2, varscan2
- MRPS22 | c.516C>A p.V172= (on ENST00000310776 / NM_001363893.1; = p.V173= on NM_020191.4) | Silent (SNP) | VAF 29/71 reads (41%) | catalogued as COSV60349628; called by muse, mutect2, varscan2
- MYH6 | c.711C>A p.V237= | Silent (SNP) | VAF 38/128 reads (30%) | catalogued as COSV62455141; called by muse, mutect2, varscan2
- NUP205 | c.4305T>C p.P1435= | Silent (SNP) | VAF 48/284 reads (17%) | catalogued as COSV53667206; called by muse, mutect2, varscan2
- OR52E6 | c.603T>C p.G201= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as rs755460609, COSV61433755; called by muse, mutect2, varscan2
- PCDH15 | c.4317G>A p.P1439= | Silent (SNP) | VAF 37/103 reads (36%) | catalogued as rs370470900; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKCD | c.1090C>T p.L364= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV57852165; called by muse, mutect2
- SLC5A12 | c.765C>A p.V255= | Silent (SNP) | VAF 36/130 reads (28%) | catalogued as COSV54825544; called by muse, mutect2, varscan2
- SPINK5 | c.1743T>C p.C581= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV56263574; called by muse, mutect2, varscan2
- TAF6 | c.462A>G p.K154= | Silent (SNP) | VAF 84/287 reads (29%) | catalogued as COSV59844351; called by muse, mutect2, varscan2
- VEGFC | c.579T>A p.S193= | Silent (SNP) | VAF 34/127 reads (27%) | catalogued as COSV54599701; called by muse, mutect2, varscan2
- SSPOP | n.15111A>G | RNA (SNP) | VAF 42/186 reads (23%) | catalogued as COSV65138719; called by muse, mutect2, varscan2
- TRAC | c.*133dup | 3'UTR (INS) | VAF 32/130 reads (25%) | catalogued as rs747854238; called by mutect2, varscan2
